Gene-level copy-number profile of tumor specimen C3L-00997-04 from CPTAC case C3L-00997, project CPTAC-3 (Oropharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 47.2 years (17,253 days).
Specimen C3L-00997-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d9329e2-a9d2-420a-b1c7-0e6757ed3fe0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00997-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/0756fea8-a270-46da-9a89-9d1545e0cbed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 485; copy number 1: 9,077; copy number 2: 24,401; copy number 3: 15,942; copy number 4: 6,686; copy number 5: 1,862; copy number 6: 238; copy number 7: 17; copy number 9: 3; copy number 12: 26; copy number 13: 170.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,128,103, 10 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:30,388,935–30,575,012, 2 genes: LINC01242, SLC4A1APP1.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,316 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,749,342–248,937,043, 134 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:194,730,595–197,676,045, 43 genes, copy number 5: LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2.
- chr3:31,161,704–31,269,406, 4 genes, copy number 5: MIR466, CNN2P6, RNA5SP127, H3P11.
- chr3:143,855,739–198,123,232, 917 genes, copy number 5–7 (broad region; genes not listed).
- chr5:191,495–2,119,926, 71 genes, copy number 5 (broad region; genes not listed).
- chr5:38,460,925–60,522,120, 255 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:37,815,777–37,819,218, 1 gene, copy number 9: AL121574.1.
- chr6:45,328,157–47,832,780, 36 genes, copy number 6 (within-gene range 2–6): RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P.
- chr8:80,628,451–80,874,781, 1 gene, copy number 6 (within-gene range 3–6): ZNF704.
- chr8:80,749,561–81,635,662, 23 genes, copy number 6: RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1.
- chr8:98,958,277–99,013,743, 3 genes, copy number 7 (within-gene range 3–7): VPS13B-DT, AC016877.1, AC104986.1.
- chr11:66,337,333–70,436,584, 170 genes, copy number 13 (within-gene range 2–13) (broad region; genes not listed).
- chr11:135,061,781–135,075,908, 1 gene, copy number 5: LINC02684.
- chr13:19,026,001–19,032,626, 2 genes, copy number 5 (within-gene range 3–5): GTF2IP3, AL137001.1.
- chr13:57,631,744–62,796,714, 42 genes, copy number 5: PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31, LINC00378, EIF4A1P6, AL161901.1, RNY3P5, LINC01442, MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, LINC00448.
- chr14:18,333,726–18,412,264, 2 genes, copy number 6–7: CR383658.1, CR383658.2.
- chr14:44,962,190–59,184,247, 261 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:105,597,691–105,669,843, 7 genes, copy number 7 (within-gene range 4–7): IGHE, IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP.
- chr14:106,482,435–106,521,073, 7 genes, copy number 5 (within-gene range 4–5): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47.
- chr14:106,556,936–106,879,812, 51 genes, copy number 5: IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr16:15,865,719–15,932,294, 4 genes, copy number 5: CEP20, RNU6-213P, AC130651.1, RPL15P20.
- chr16:60,346,478–61,055,964, 7 genes, copy number 5: AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16.
- chr19:14,840,466–17,895,174, 176 genes, copy number 5 (broad region; genes not listed).
- chr21:7,744,962–10,649,835, 68 genes, copy number 5–12 (broad region; genes not listed).
- chr22:49,414,524–50,180,295, 30 genes, copy number 6: C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1, PANX2.

Autosomal genes at a single copy (total copy number 1): 6,715. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
